Somatic mutation profile of tumor specimen TCGA-FK-A3SB-01A (aliquot TCGA-FK-A3SB-01A-11D-A22D-08) from TCGA case TCGA-FK-A3SB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.2 years (10,293 days).
Specimen TCGA-FK-A3SB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2c6ea61-9a76-4964-98ea-e6b07f7e5543.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FK-A3SB-10A (Blood Derived Normal), aliquot TCGA-FK-A3SB-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc274d22-4922-46ab-9dc4-5fdf609d9dc9

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ESPN | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV64705544; called by muse, mutect2, varscan2
- GMIP | c.536A>G p.Q179R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52560347; called by muse, mutect2, varscan2
- ZFHX3 | c.3641C>G p.A1214G | Missense Mutation (SNP) | VAF 140/392 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as COSV51738899; called by muse, mutect2, varscan2
- EIF3L | c.360A>G p.P120= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV67740228; called by muse, mutect2, varscan2
- VGLL3 | c.840A>G p.T280= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1232393862, COSV67354623; called by muse, mutect2, varscan2
